Gene-level copy-number profile of tumor specimen ALCH-B3ZA-TTP1-A from ALCHEMIST case ALCH-B3ZA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 67.1 years (24,512 days).
Specimen ALCH-B3ZA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 897e9729-ecb2-4a9b-935f-df862e9c3581.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3ZA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/a94b94e5-d3ae-4a27-acb1-4e72a3ffb3b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 108; copy number 1: 16,871; copy number 2: 27,645; copy number 3: 9,026; copy number 4: 2,234; copy number 5: 1,865; copy number 6: 103; copy number 8: 5; copy number 9: 64; copy number 10: 462; copy number 22: 1.

Homozygous deletions (total copy number 0; autosomes only): 108 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:131,821,987–131,822,920, 1 gene: AC103564.3.
- chr3:49,674,014–49,723,973, 6 genes (within-gene range 0–1): APEH, MST1, AC099668.1, RNF123, AMIGO3, GMPPB.
- chr8:43,539,137–43,544,057, 3 genes: AC134698.5, CYP4F44P, AC134698.2.
- chr9:67,697,076–67,726,255, 5 genes: Y_RNA, FAM27E3, AL627230.3, FAM27B, AL627230.1.
- chr11:45,885,651–45,918,812, 4 genes: MAPK8IP1, AC068385.1, C11orf94, PEX16.
- chr14:104,865,268–104,896,770, 1 gene: CEP170B.
- chr15:25,193,321–25,243,695, 28 genes (within-gene range 0–1): SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40.
- chr15:28,857,882–29,118,315, 4 genes (within-gene range 0–1): AC174071.1, AC174469.1, APBA2, AC127522.1.
- chr15:41,825,099–41,848,155, 4 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–2): RNA5SP393.
- chr15:45,129,933–45,167,526, 2 genes (within-gene range 0–1): DUOX1, AC051619.5.
- chr15:67,819,704–67,873,866, 4 genes: SKOR1, AC009292.2, AC009292.1, RNU6-1.
- chr15:73,319,859–73,368,958, 2 genes: HCN4, AC068397.2.
- chr16:35,169,692–35,284,146, 12 genes: UBE2MP1, SLC25A1P4, AC023824.1, AC023824.2, AC023824.4, AC023824.3, TP53TG3GP, RARRES2P5, FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8.
- chr16:35,414,279–35,645,180, 21 genes: RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP, AC018558.5, RARRES2P8, AGGF1P7, C2orf69P1, C1QL1P1, KIF18BP1, AC092325.1.
- chr16:56,300,616–56,353,524, 3 genes (within-gene range 0–1): AC009102.1, AC009102.3, AC009102.2.
- chr16:57,668,277–57,689,378, 1 gene (within-gene range 0–2): ADGRG3.
- chr16:67,205,175–67,272,191, 6 genes: AC040160.2, LRRC29, TMEM208, FHOD1, SLC9A5, AC040160.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,500 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,401,069–155,885,199, 524 genes, copy number 9–10 (broad region; genes not listed).
- chr1:237,943,724–238,779,200, 12 genes, copy number 5: MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2.
- chr2:176,077,472–177,559,299, 53 genes, copy number 5–6 (within-gene range 3–6): EVX2, HOXD13, HOXD12, HOXD11, HOXD10, HOXD-AS2, HOXD9, HOXD8, HOXD3, MIR10B, HOXD4, HAGLR, AC009336.1, HAGLROS, HOXD1, MIR7704, AC009336.2, AC016739.1, RPSAP25, MTX2, PPIAP67, LINC01117, AC017048.1, AC017048.2, AC017048.3, LINC01116, RNU6ATAC14P, AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1, RNU6-187P, AC074286.1, AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2, AGPS.
- chr2:186,827,475–187,003,377, 2 genes, copy number 6 (within-gene range 3–6): ZSWIM2, IMPDH1P7.
- chr2:206,939,518–212,538,841, 77 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:196,739,857–196,832,647, 3 genes, copy number 8: PAK2, RNU4-89P, RNU6-42P.
- chr6:27,737,000–28,189,432, 44 genes, copy number 6: GPR89P, RSL24D1P1, H4C10P, H2BC13, H2AC13, H3C10, H2AC14, H2BC14, H4C11, H4C12, H2BC15, H2AC15, H2BC16P, H2AC16, H1-5, H3C11, H4C13, H3C12, H2AC17, H2BC17, RNU7-26P, OR2B2, OR2W6P, OR2B6, RPLP2P1, OR2W4P, IQCB2P, ZSCAN16-AS1, U3, OR2W2P, OR2B7P, OR2B8P, OR1F12, AL121944.1, ZNF165, ZSCAN12P1, ZNF602P, ZSCAN16, AL358933.1, ZKSCAN8, ZNF192P1, AL022393.1, ZNF603P, ZNF192P2.
- chr7:74,633,510–74,851,551, 6 genes, copy number 5–6: AC211433.3, GTF2I, AC211433.1, PHBP15, NCF1, GTF2IRD2.
- chr7:135,361,795–135,510,127, 1 gene, copy number 6 (within-gene range 4–6): CNOT4.
- chr7:150,676,833–150,861,504, 10 genes, copy number 5: AC069304.2, GIMAP2, GIMAP1, GIMAP1-GIMAP5, GIMAP5, GIMAP3P, BET1P1, TMEM176B, TMEM176A, AOC1.
- chr7:151,232,489–151,520,120, 14 genes, copy number 5: CHPF2, MIR671, SMARCD3, AC021097.1, AC005486.1, NUB1, WDR86, WDR86-AS1, AC005996.1, CRYGN, MIR3907, RN7SL76P, RHEB, ETF1P2.
- chr9:64,810,865–64,811,429, 1 gene, copy number 6: BNIP3P4.
- chr9:64,878,790–64,889,063, 2 genes, copy number 8: AC125634.1, RNU6-1293P.
- chr12:190,077–32,896,777, 806 genes, copy number 5–6 (broad region; genes not listed).
- chr17:22,567,423–22,706,703, 5 genes, copy number 5: AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.
- chr17:50,094,065–51,297,936, 64 genes, copy number 5 (broad region; genes not listed).
- chr17:55,882,301–80,209,331, 710 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:80,351,828–83,240,804, 160 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:30,219,666–30,228,715, 1 gene, copy number 5 (within-gene range 3–5): AC005597.1.
- chr20:30,214,765–30,214,976, 1 gene, copy number 5: CFTRP3.
- chr21:43,053,191–43,107,570, 2 genes, copy number 10–22: CBS, U2AF1.
- chr21:43,115,334–43,141,092, 2 genes, copy number 6–10: MRPL51P2, FRGCA.

Autosomal genes at a single copy (total copy number 1): 15,108. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
